MMRF case MMRF_1205 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d138a040-c9b8-411e-8997-f83f8a58ea34

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 78 years; Vital status: Dead; Days to death: 976 days (2.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.0 years (28,843 days); ISS stage: III; Days to last known disease status: 976 days (2.7 years); Days to last follow up: 976 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 114 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 135 days; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 187 days; Days to treatment end: 187 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 189 days; Days to treatment end: 189 days.
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 618 days (1.7 years); Days to treatment end: 666 days (1.8 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 667 days (1.8 years); Days to treatment end: 685 days (1.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 2): M Protein 5.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 75.3 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 5.82 µg/mL; Lactate Dehydrogenase 1.65 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 287 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 27 g/L; Total Protein 11.6 g/dL; Glucose 5.17 mmol/L.
- Day 85 (ECOG 1): M Protein 3.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.652 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 33.5 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 3.15 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 1.85 mmol/L; Albumin 32 g/L; Total Protein 8.7 g/dL; Glucose 5.72 mmol/L.
- Day 182 (ECOG 1): M Protein 2.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.729 mg/dL; Immunoglobulin G 26.8 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 12.8 µkat/L; Hemoglobin 4.96 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.08 mmol/L; Albumin 31 g/L; Total Protein 7.7 g/dL; Glucose 3.69 mmol/L.
- Day 244 (ECOG 1): M Protein 0.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.66 mg/dL; Immunoglobulin G 18.9 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.38 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.5 mmol/L.
- Day 370 (ECOG 1): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 5.34 mmol/L.
- Day 426 (ECOG 1): M Protein 0.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.06 mmol/L.
- Day 552 (ECOG 1): M Protein 1.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.731 mg/dL; Immunoglobulin G 18.1 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 632 (ECOG 1): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.48 mg/dL; Immunoglobulin G 19.8 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 6.27 mmol/L.
- Day 695 (ECOG 3): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 4.62 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 1.9 mmol/L; Albumin 18 g/L; Total Protein 5.7 g/dL; Glucose 5.61 mmol/L.
- Day 801 (ECOG 4): M Protein 2.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.898 mg/dL; Immunoglobulin G 39.6 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.4 µg/mL; Hemoglobin 5.89 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.75 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 26.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.05 mmol/L; Albumin 22 g/L; Total Protein 7.5 g/dL; Glucose 5.01 mmol/L.
- Day 880 (ECOG 4): M Protein 4.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 52.9 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 5.46 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.1 mmol/L; Albumin 22 g/L; Total Protein 8.9 g/dL; Glucose 5.23 mmol/L.
- Day 976: M Protein 5.03 g/dL; Immunoglobulin G 69.5 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 7.8 µg/mL; Hemoglobin 5.33 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 17.5 mmol/L; Calcium 1.88 mmol/L; Albumin 26 g/L; Total Protein 10.7 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -13: Weight: 77 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1205_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 552 days (1.5 years).
- Sample MMRF_1205_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 552 days (1.5 years).
